Somatic mutation profile of tumor specimen TARGET-40-PARKAF-01A (aliquot TARGET-40-PARKAF-01A-01D) from TARGET case TARGET-40-PARKAF, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.7 years (6,085 days).
Specimen TARGET-40-PARKAF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d713cefb-99b9-47ed-8ae5-cad6ed6ee99e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PARKAF-10A (Blood Derived Normal), aliquot TARGET-40-PARKAF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fb810a2-2f5a-4bd0-a5b6-d931af1d25c1

The open-access MAF lists 25 somatic variants for this specimen: 10 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 9, Missense Mutation 9, Intron 2, 3'UTR 1, RNA 1, 5'UTR 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGHV4-28 | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as rs782569526; called by muse, mutect2, varscan2
- MIER2 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs774182372; called by muse, mutect2, varscan2
- MYO18B | c.6371G>C p.S2124T | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as rs377728283; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2539C>T p.R847W | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs148557417; called by muse, mutect2, varscan2
- ST8SIA2 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 10/74 reads (14%) | PolyPhen possibly damaging (0.901); catalogued as rs201692548, COSV51566823; called by mutect2, varscan2
- C1orf112 | c.984G>C p.L328F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEACAM18 | c.674-1G>A p.X225_splice | Splice Site (SNP) | VAF 26/88 reads (30%) | called by mutect2, varscan2
- DMD | c.5272T>C p.S1758P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IGHE | c.733G>C p.A245P | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- RANBP2 | c.1610C>T p.T537I | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ABHD17C | c.732G>A p.P244= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs1006840419; called by muse, mutect2, varscan2
- ACSM2A | c.13C>A p.R5= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs368922104, COSV99525147; called by mutect2, varscan2
- ADAMTS2 | c.912C>T p.D304= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs147197558; called by muse, mutect2, varscan2
- ADGRE1 | c.1965T>C p.G655= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1450917202; called by mutect2, varscan2
- IL1RN | c.447G>T p.A149= (on ENST00000409930 / NM_173842.3; = p.A131= on NM_000577.5) | Silent (SNP) | VAF 14/82 reads (17%) | called by mutect2, varscan2
- KIF2B | c.168C>T p.V56= | Silent (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- KIRREL1 | c.315C>T p.A105= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs748898038, COSV63286890; called by muse, mutect2, varscan2
- MYO18B | c.123G>A p.L41= | Silent (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- ZNF766 | c.465G>A p.G155= | Silent (SNP) | VAF 30/139 reads (22%) | called by muse, mutect2, varscan2
- CRHR1 | c.796+51G>T | Intron (SNP) | VAF 7/40 reads (18%) | called by mutect2, varscan2
- FCGR3B | c.62-67C>A | Intron (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457445 C>A | 5'Flank (SNP) | VAF 18/61 reads (30%) | called by mutect2, varscan2
- PGLYRP4 | c.*118C>T | 3'UTR (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- TRAV8-6 | c.-39G>A | 5'UTR (SNP) | VAF 23/68 reads (34%) | catalogued as rs755175356; called by muse, mutect2, varscan2
- TRIM60P14 | n.611T>C | RNA (SNP) | VAF 7/36 reads (19%) | catalogued as rs56056003; called by muse, mutect2, varscan2
